Somatic mutation profile of cancer-model specimen HCM-CSHL-0461-D12-85P (3D Organoid; aliquot HCM-CSHL-0461-D12-85P-01D-A78U-36), derived from the premalignant tumor of HCMI case HCM-CSHL-0461-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Serrated adenoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 54.7 years (19,976 days).
Specimen HCM-CSHL-0461-D12-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ba32599-d47c-4c95-85d8-7999b577a696.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0461-D12-10A (Blood Derived Normal), aliquot HCM-CSHL-0461-D12-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/267b93f1-5688-4d35-b7ea-471d4ce47bf9

The open-access MAF lists 116 somatic variants for this specimen: 81 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 30, Nonsense Mutation 7, Intron 4, Frame Shift Ins 4, Splice Region 3, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 129/271 reads (48%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 68/719 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 56/181 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 38/314 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.692dup p.S232Qfs*3 | Frame Shift Ins (INS) | VAF 151/398 reads (38%) | catalogued as rs377767334, COSV61691229; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 84/177 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs137986624, COSV61004801; called by muse, mutect2
- ADAMTS18 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV51414962; called by muse, mutect2
- ADAMTSL3 | c.2177G>T p.R726L | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54467957; called by muse, mutect2
- ADAMTSL3 | c.3415C>T p.R1139W | Missense Mutation (SNP) | VAF 87/194 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs145388431; called by muse, mutect2, varscan2
- APC | c.4243dup p.S1415Kfs*8 | Frame Shift Ins (INS) | VAF 83/226 reads (37%) | catalogued as COSV57328975; called by mutect2, pindel, varscan2
- ASB10 | c.793G>A p.D265N (on ENST00000420175 / NM_001142459.2; = p.D250N on NM_080871.4) | Missense Mutation (SNP) | VAF 35/347 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs200652340; called by muse, mutect2
- BIRC7 | c.787G>A p.V263I (on ENST00000217169 / NM_139317.3; = p.V245I on NM_022161.4) | Missense Mutation (SNP) | VAF 117/574 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1211741916, COSV53903059; called by muse, mutect2, varscan2
- BRD4 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs781618267; called by muse, mutect2, varscan2
- CSMD2 | c.8248G>A p.G2750S | Missense Mutation (SNP) | VAF 178/362 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs144107939; called by muse, mutect2, varscan2
- DDRGK1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs765906690, COSV100621416; called by muse, mutect2, varscan2
- DNAH5 | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 218/457 reads (48%) | catalogued as rs778780449, COSV54220884; called by muse, mutect2, varscan2
- DNHD1 | c.13634C>T p.P4545L | Missense Mutation (SNP) | VAF 109/205 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54435909; called by muse, mutect2, varscan2
- DYNC2H1 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 12/145 reads (8%) | catalogued as rs1474159674, COSV100519899; called by muse, mutect2
- EPB41L1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 102/568 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759662141, COSV52437690; called by muse, mutect2, varscan2
- FLG | c.1444C>A p.H482N | Missense Mutation (SNP) | VAF 239/538 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs745468641; called by muse, mutect2, varscan2
- FRG2C | c.821C>A p.S274* | Nonsense Mutation (SNP) | VAF 144/810 reads (18%) | catalogued as rs1392451749; called by muse, mutect2
- GRIN2A | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 176/414 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58034105; called by muse, mutect2, varscan2
- IFT88 | c.1413+12dup | Splice Region (INS) | VAF 50/124 reads (40%) | catalogued as rs769655324; called by mutect2, varscan2
- INTS6 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 109/250 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as rs1372857363, COSV60878750; called by muse, mutect2, varscan2
- LILRA4 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 114/456 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs139101339; called by muse, varscan2
- MINK1 | c.3929C>T p.S1310L | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs774790111; called by muse, mutect2, varscan2
- NOL4 | c.449C>A p.A150E | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52345895; called by muse, mutect2, varscan2
- NPBWR2 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV63899936; called by muse, mutect2, varscan2
- NT5C3A | c.217G>C p.G73R (on ENST00000610140 / NM_001374335.1; = p.G39R on NM_016489.13) | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV54238498; called by muse, mutect2, varscan2
- OTOF | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as rs142370721; called by muse, mutect2, varscan2
- PCBP1 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- RAP1GDS1 | c.361C>T p.H121Y (on ENST00000408927 / NM_001100427.2; = p.H122Y on NM_021159.5) | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.253); catalogued as COSV99216964; called by muse, mutect2
- RNFT2 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.992); catalogued as rs148512260, COSV57487003; called by muse, mutect2, varscan2
- ROBO2 | c.1478C>G p.S493* | Nonsense Mutation (SNP) | VAF 102/223 reads (46%) | catalogued as COSV100163019, COSV59950025; called by muse, mutect2, varscan2
- SERPINA10 | c.410A>G p.K137R | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV104381644; called by muse, mutect2
- SETD1B | c.4409C>T p.T1470M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.584); catalogued as rs1490141875; called by muse, mutect2, varscan2
- SLC6A11 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757531916; called by muse, mutect2, varscan2
- SLFN11 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 31/497 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs746690453; called by muse, mutect2
- SMARCAD1 | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs750694296; called by muse, mutect2
- SOX9 | c.886C>G p.Q296E | Missense Mutation (SNP) | VAF 34/432 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV55423365; called by muse, mutect2
- STAG1 | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 104/249 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV99365835; called by muse, mutect2, varscan2
- STRC | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 220/1021 reads (22%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as rs1399374103; called by muse, mutect2, varscan2
- SULF1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758690728, COSV52674097; called by muse, mutect2, varscan2
- THOC5 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 88/170 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.372); catalogued as rs141199207; called by muse, mutect2, varscan2
- TPCN2 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541105565; called by muse, mutect2, varscan2
- TRIOBP | c.7078C>T p.R2360C (on ENST00000644935 / NM_001039141.3; = p.R647C on NM_007032.5) | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.036); catalogued as rs371230470; called by muse, mutect2, varscan2
- UBE4B | c.2581G>A p.A861T (on ENST00000343090 / NM_001105562.3; = p.A732T on NM_006048.5) | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs147329205, COSV53532772; called by muse, mutect2, varscan2
- UTP20 | c.4994C>T p.T1665M | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs753325126; called by muse, mutect2
- ZFHX4 | c.1981G>T p.A661S | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99269376; called by muse, mutect2
- ZFP36L2 | c.303dup p.K102* | Frame Shift Ins (INS) | VAF 80/404 reads (20%) | catalogued as COSV56700443; called by mutect2, pindel, varscan2
- ZNF469 | c.11483G>A p.R3828H (on ENST00000437464; = p.R3856H on NM_001367624.2) | Missense Mutation (SNP) | VAF 209/394 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs187075195, COSV71259370; called by muse, mutect2, varscan2
- ZNF628 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs920009714; called by muse, mutect2, varscan2
- ZNF878 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 196/427 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs777626762, COSV72155963; called by muse, varscan2
- BOK | c.583T>C p.C195R | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- CEL | c.1451C>G p.S484C (on ENST00000673714; = p.S481C on NM_001807.6) | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DHX38 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- DOCK2 | c.3627T>C p.N1209= | Splice Region (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- DUSP5 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 66/322 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FLG | c.10183C>A p.Q3395K | Missense Mutation (SNP) | VAF 87/650 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FMNL2 | c.951+5G>A | Splice Region (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- FOXF2 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPATCH8 | c.4075A>T p.I1359F | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.36); called by muse, mutect2
- ITGA7 | c.1360A>T p.K454* (on ENST00000555728; = p.K410* on NM_002206.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 85/312 reads (27%) | called by muse, mutect2, varscan2
- MYO1F | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 143/302 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- PPP1R7 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PPP4R3C | c.281G>C p.W94S | Missense Mutation (SNP) | VAF 123/123 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM47 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SF3B4 | c.1171C>G p.P391A | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SIN3A | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC16A13 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.348); called by muse, mutect2
- SMC3 | c.350+1G>C p.X117_splice | Splice Site (SNP) | VAF 68/170 reads (40%) | called by muse, mutect2, varscan2
- STYK1 | c.1030A>G p.I344V | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- TLE3 | c.2119A>T p.K707* | Nonsense Mutation (SNP) | VAF 19/182 reads (10%) | called by muse, varscan2
- TMEM87A | c.836A>T p.E279V | Missense Mutation (SNP) | VAF 70/124 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.4370C>T p.P1457L (on ENST00000591111; = p.P1411L on NM_003319.4) | Missense Mutation (SNP) | VAF 93/208 reads (45%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC79 | c.4989dup p.A1664Cfs*36 (on ENST00000393151 / NM_001346218.2; = p.A1487Cfs*36 on NM_020818.5) | Frame Shift Ins (INS) | VAF 28/173 reads (16%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.5272C>A p.P1758T | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- ZNF423 | c.598A>G p.K200E (on ENST00000563137 / NM_001379286.1; = p.K192E on NM_015069.4) | Missense Mutation (SNP) | VAF 39/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF827 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 114/248 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- A2M | c.1641T>A p.P547= | Silent (SNP) | VAF 59/196 reads (30%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.2343C>T p.N781= | Silent (SNP) | VAF 12/177 reads (7%) | catalogued as rs370729317; called by muse, mutect2
- ANKRD33B | c.1443G>A p.A481= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as rs1431975126; called by muse, mutect2
- BIVM-ERCC5 | c.621A>T p.R207= | Silent (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- BORCS5 | c.507G>C p.L169= | Silent (SNP) | VAF 181/389 reads (47%) | called by muse, mutect2, varscan2
- CHRM3 | c.1752C>T p.R584= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as rs201601302, COSV55085033; called by muse, mutect2, varscan2
- CSF1R | c.327C>T p.N109= | Silent (SNP) | VAF 97/204 reads (48%) | catalogued as rs781316589; called by muse, mutect2, varscan2
- DELE1 | c.966C>T p.C322= | Silent (SNP) | VAF 117/257 reads (46%) | called by muse, mutect2, varscan2
- DIP2A | c.4347C>T p.H1449= | Silent (SNP) | VAF 23/187 reads (12%) | catalogued as rs752202862, COSV59488667; called by muse, mutect2, varscan2
- EML6 | c.4791C>T p.P1597= | Silent (SNP) | VAF 19/185 reads (10%) | catalogued as rs766353066; called by muse, mutect2, varscan2
- FAT4 | c.10503C>T p.T3501= | Silent (SNP) | VAF 49/222 reads (22%) | called by muse, mutect2, varscan2
- FAT4 | c.13617C>A p.P4539= | Silent (SNP) | VAF 175/337 reads (52%) | called by muse, mutect2
- HBG1 | c.150C>A p.S50= | Silent (SNP) | VAF 52/542 reads (10%) | catalogued as COSV100400649; called by muse, varscan2
- ITGA7 | c.1359G>T p.G453= (on ENST00000555728; = p.G409= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/308 reads (27%) | called by muse, mutect2, varscan2
- KRT74 | c.867C>T p.H289= | Silent (SNP) | VAF 28/509 reads (6%) | catalogued as rs371350159; called by muse, mutect2
- MPZ | c.651A>G p.P217= | Silent (SNP) | VAF 26/188 reads (14%) | called by muse, mutect2, varscan2
- MYO1B | c.541C>T p.L181= | Silent (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.1560C>T p.F520= | Silent (SNP) | VAF 16/305 reads (5%) | catalogued as COSV52770644; called by muse, mutect2
- PDILT | c.1323C>A p.I441= | Silent (SNP) | VAF 42/230 reads (18%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.6564A>G p.G2188= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs769223422, COSV65737892; called by muse, mutect2, varscan2
- RB1CC1 | c.1677C>A p.P559= | Silent (SNP) | VAF 31/118 reads (26%) | called by muse, mutect2, varscan2
- RBM45 | c.306C>T p.F102= | Silent (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- RBM46 | c.351C>G p.A117= | Silent (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- RPL5 | c.114A>T p.I38= | Silent (SNP) | VAF 37/272 reads (14%) | called by muse, mutect2, varscan2
- SETBP1 | c.4164G>A p.S1388= | Silent (SNP) | VAF 125/263 reads (48%) | catalogued as rs773446890, COSV56320238; called by muse, mutect2, varscan2
- SHROOM3 | c.3210G>A p.T1070= | Silent (SNP) | VAF 199/681 reads (29%) | called by muse, mutect2, varscan2
- SMARCA2 | c.1998C>T p.S666= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as rs765966954, COSV100570714, COSV61812664; called by muse, mutect2
- TMEM134 | c.483C>T p.G161= | Silent (SNP) | VAF 25/360 reads (7%) | called by muse, mutect2
- UMAD1 | c.324C>T p.P108= | Silent (SNP) | VAF 22/380 reads (6%) | catalogued as rs533343675; called by muse, mutect2
- ZBTB39 | c.1173C>T p.V391= | Silent (SNP) | VAF 46/300 reads (15%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-10426A>G | Intron (SNP) | VAF 67/193 reads (35%) | called by muse, mutect2, varscan2
- DNM3 | c.1689+7607G>T | Intron (SNP) | VAF 25/308 reads (8%) | called by muse, mutect2
- TCTN1 | c.*29A>T | 3'UTR (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- VCP | c.1194+33C>T | Intron (SNP) | VAF 38/350 reads (11%) | called by muse, mutect2, varscan2
- ZNF692 | c.-12-165A>G | Intron (SNP) | VAF 125/270 reads (46%) | called by muse, mutect2, varscan2
